Somatic mutation profile of tumor specimen 0DUUQB from CCDI case PBCLYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,137 days).
Specimen 0DUUQB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aef95b6-70b6-43dc-a9a1-1ab4822e1451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683091ac-9761-498c-b7cc-bc2b0c03f6f9

The open-access MAF lists 25 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 6, Silent 5, In Frame Del 1, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1B | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs376475947; called by muse, mutect2
- CALHM1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368732643; called by muse, mutect2, varscan2
- MAGEC3 | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV68924408; called by muse, mutect2
- MYH6 | c.5292C>T p.A1764= | Splice Region (SNP) | VAF 72/177 reads (41%) | catalogued as rs753745013; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEDD9 | c.2226C>G p.F742L | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101060758; called by muse, mutect2
- TNXB | c.3616C>T p.R1206C (on ENST00000647633; = p.R959C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs749923458; called by muse, mutect2, varscan2
- USF3 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 106/361 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201006777, COSV57072020; called by muse, mutect2, varscan2
- CIT | c.3847C>A p.R1283S | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EZR | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2
- IER2 | c.407T>G p.V136G | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- RAB32 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RIF1 | c.2997_3017del p.R1000_R1006del | In Frame Del (DEL) | VAF 29/195 reads (15%) | called by mutect2, pindel, varscan2
- ANKS3 | c.921C>T p.P307= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- CPN2 | c.1587C>T p.C529= | Silent (SNP) | VAF 62/196 reads (32%) | catalogued as rs149812386; called by muse, mutect2, varscan2
- OR4A16 | c.741C>T p.L247= | Silent (SNP) | VAF 93/306 reads (30%) | catalogued as rs1346457574, COSV100125249, COSV59043426, COSV59045211; called by muse, mutect2, varscan2
- SLC1A6 | c.372G>A p.T124= | Silent (SNP) | VAF 20/205 reads (10%) | catalogued as rs375572442; called by muse, mutect2, varscan2
- XPO5 | c.2706C>T p.F902= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as COSV54835869; called by muse, mutect2, varscan2
- AL645922.1 | c.256+697G>A | Intron (SNP) | VAF 15/342 reads (4%) | catalogued as rs367996721; ClinVar: uncertain significance; called by muse, mutect2
- EIF4E | c.-49del | 5'UTR (DEL) | VAF 30/119 reads (25%) | catalogued as rs1288293693; called by mutect2, pindel, varscan2
- FAM98C | c.918+28_918+30del | Intron (DEL) | VAF 19/174 reads (11%) | called by mutect2, pindel, varscan2
- IRF9 | c.650-70T>C | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as rs1377656233; called by muse, mutect2
- PIFO | c.259-39T>G | Intron (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.358-51G>A | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as rs774348822; called by muse, mutect2, varscan2
- TFDP1 | c.308+59C>T | Intron (SNP) | VAF 47/100 reads (47%) | catalogued as rs562619736; called by muse, mutect2, varscan2
- ZSWIM6 | c.*4A>C | 3'UTR (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
